Somatic mutation profile of tumor specimen TCGA-LN-A4A8-01A (aliquot TCGA-LN-A4A8-01A-32D-A27G-09) from TCGA case TCGA-LN-A4A8, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 52.1 years (19,046 days).
Specimen TCGA-LN-A4A8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9b20eb03-aa1b-4fe5-ab34-9cdf1e79fe61.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A8-10A (Blood Derived Normal), aliquot TCGA-LN-A4A8-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7a4244dd-bf4e-4fb7-a1da-8ceefac2cb5d

The open-access MAF lists 125 somatic variants for this specimen: 83 protein-altering or splice-affecting, 37 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, Silent 37, Nonsense Mutation 6, Frame Shift Ins 3, In Frame Del 2, Frame Shift Del 2, Intron 2, RNA 1, 3'UTR 1, 5'UTR 1, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 295/403 reads (73%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- VWF | c.3943C>T p.R1315C | Missense Mutation (SNP) | VAF 65/750 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61749395, CM1211904, CM941402, COSV54618838; ClinVar: likely pathogenic; called by muse, mutect2
- ANKRD17 | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.767); catalogued as COSV100429979; called by muse, mutect2
- APEH | c.818G>T p.R273L | Missense Mutation (SNP) | VAF 48/87 reads (55%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV99610767; called by muse, mutect2, varscan2
- ARRB1 | c.800C>T p.T267M | Missense Mutation (SNP) | VAF 24/38 reads (63%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as rs200557530, COSV63577303; called by muse, mutect2, varscan2
- CCNF | c.459C>G p.I153M | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1268775342; called by muse, mutect2
- CIC | c.1046C>T p.S349L | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.108); catalogued as COSV99031281; called by muse, mutect2, varscan2
- CXCR2 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 3/45 reads (7%) | catalogued as COSV59281698; called by muse, mutect2
- FAT4 | c.2110G>A p.G704R | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.888); catalogued as COSV67884773; called by muse, mutect2, varscan2
- HCN3 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100751768, COSV62876739; called by muse, mutect2, varscan2
- LURAP1L | c.30A>T p.R10S | Missense Mutation (SNP) | VAF 30/50 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV59986339; called by muse, mutect2, varscan2
- MRPL58 | c.155C>G p.S52C | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as COSV100043004; called by muse, mutect2, varscan2
- MYH2 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 7/34 reads (21%) | catalogued as rs769712128; called by muse, mutect2, varscan2
- OR14J1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs753138884; called by muse, mutect2, varscan2
- OR2C1 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs772065321; called by muse, mutect2, varscan2
- OR5H15 | c.899C>G p.S300* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV62947496, COSV62948489; called by muse, mutect2, varscan2
- PCDH15 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs372085398; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RMC1 | c.1958G>A p.R653K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1440279530; called by muse, mutect2, varscan2
- RP1L1 | c.4642C>A p.Q1548K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as rs574264133; called by muse, mutect2, varscan2
- SH2D3C | c.1663C>T p.P555S (on ENST00000314830 / NM_170600.3; = p.P398S on NM_005489.4) | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs375337324; called by muse, mutect2, varscan2
- SLC15A1 | c.1150-1G>C p.X384_splice | Splice Site (SNP) | VAF 3/44 reads (7%) | catalogued as COSV64731267; called by muse, mutect2
- SLC33A1 | c.1307A>G p.N436S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.102); catalogued as COSV63947521; called by muse, mutect2, varscan2
- SLCO1A2 | c.1241C>T p.S414L | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as rs1474907564, COSV56599539; called by muse, mutect2, varscan2
- SNTG1 | c.902G>T p.R301I | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as COSV52462211; called by muse, mutect2, varscan2
- TMEM41B | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.09); catalogued as COSV55154323; called by muse, mutect2
- UPK1B | c.577A>G p.M193V | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV51768109; called by muse, mutect2, varscan2
- VPS45 | c.42G>C p.M14I | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as rs1212200860; called by muse, mutect2
- YAP1 | c.1266G>C p.E422D (on ENST00000282441 / NM_001130145.3; = p.E368D on NM_006106.5) | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as COSV56773606; called by muse, mutect2, varscan2
- YLPM1 | c.5213G>A p.R1738Q | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.731); catalogued as rs754951613; called by muse, varscan2
- ZBTB18 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs373838988; called by muse, mutect2, varscan2
- ZNF460 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV99081836; called by muse, mutect2, varscan2
- ABCC12 | c.50G>T p.R17L | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- AFF3 | c.1976T>C p.V659A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALG6 | c.1158_1160del p.L387del | In Frame Del (DEL) | VAF 8/24 reads (33%) | called by mutect2, varscan2
- APH1A | c.767del p.Y256Ffs*14 | Frame Shift Del (DEL) | VAF 15/50 reads (30%) | called by mutect2, pindel, varscan2
- ARFGEF3 | c.2519C>G p.T840R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.58); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- BCO1 | c.1643G>C p.*548Sext*60 | Nonstop Mutation (SNP) | VAF 8/48 reads (17%) | called by muse, varscan2
- CCR10 | c.418G>T p.V140L | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CD163 | c.779A>G p.K260R | Missense Mutation (SNP) | VAF 35/168 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- CEP83 | c.710A>T p.E237V | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CHD2 | c.2441C>G p.S814C | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CMTM3 | c.225_226dup p.L76Pfs*15 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel
- CPNE5 | c.796G>T p.E266* | Nonsense Mutation (SNP) | VAF 13/24 reads (54%) | called by muse, mutect2, varscan2
- DACH2 | c.1199C>A p.S400Y | Missense Mutation (SNP) | VAF 14/20 reads (70%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); called by muse, varscan2
- DCDC2 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- DENND6A | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 22/45 reads (49%) | called by muse, mutect2, varscan2
- DNMT1 | c.1230C>T p.F410= | Splice Region (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- DOCK10 | c.5195_5196dup p.Y1733Sfs*3 | Frame Shift Ins (INS) | VAF 6/27 reads (22%) | called by mutect2, pindel, varscan2
- ERI2 | c.77G>C p.G26A | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2
- FAM131A | c.939A>T p.Q313H (on ENST00000310585; = p.Q344H on NM_144635.5) | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- GATA1 | c.382G>A p.G128S | Missense Mutation (SNP) | VAF 23/33 reads (70%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRIK2 | c.2082C>G p.F694L | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A1 | c.738G>T p.E246D | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.39); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HAL | c.524G>C p.R175T | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2
- IGSF6 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRX5 | c.589G>C p.E197Q | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KRI1 | c.1635_1636insTT p.K546Lfs*4 | Frame Shift Ins (INS) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- LIMCH1 | c.1570C>G p.P524A | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- MEGF8 | c.4827G>C p.E1609D (on ENST00000251268 / NM_001271938.2; = p.E1542D on NM_001410.3) | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.53); called by muse, mutect2
- NDST1 | c.329A>G p.K110R | Missense Mutation (SNP) | VAF 21/38 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NUBPL | c.54_80del p.G19_G27del | In Frame Del (DEL) | VAF 23/60 reads (38%) | called by mutect2, pindel, varscan2
- PALM2AKAP2 | c.628C>A p.Q210K (on ENST00000374531 / NM_001037293.2; = p.Q242K on NM_053016.6) | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- PARD6B | c.945G>C p.E315D | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- PLAAT1 | c.646G>C p.A216P (on ENST00000650797; = p.A111P on NM_020386.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RAB8B | c.400G>C p.E134Q | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.187); called by muse, mutect2
- RBMS2 | c.421A>G p.N141D | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- REPS1 | c.1600A>G p.R534G (on ENST00000450536 / NM_001286611.2; = p.R533G on NM_031922.4) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RP1L1 | c.5539G>C p.E1847Q | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- RPAP2 | c.1795G>T p.E599* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | called by muse, mutect2, varscan2
- RTP4 | c.128A>T p.K43M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SLC25A15 | c.335C>G p.A112G | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- STAG1 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.602); called by muse, mutect2, varscan2
- STARD3 | c.505C>T p.L169F | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SWAP70 | c.753A>T p.K251N | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- TANGO6 | c.958C>G p.Q320E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- TARS1 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- TBC1D15 | c.1583G>T p.C528F | Missense Mutation (SNP) | VAF 49/106 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TDRKH | c.1579_1589del p.T527Lfs*22 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- TNN | c.3038C>T p.T1013I | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2
- TXNRD2 | c.774G>T p.Q258H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- WASHC5 | c.2133G>C p.R711S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- WDR89 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated (0.31); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZNF302 | c.1268G>A p.R423K (on ENST00000627982; = p.R344K on NM_018443.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/64 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ABCA8 | c.4008G>C p.V1336= | Silent (SNP) | VAF 44/94 reads (47%) | called by muse, mutect2
- ADGRB2 | c.2190C>G p.P730= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs140390564; called by muse, mutect2, varscan2
- ANKRD13C | c.384C>G p.L128= | Silent (SNP) | VAF 10/57 reads (18%) | called by muse, mutect2, varscan2
- ARHGAP10 | c.1626G>C p.L542= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- ATR | c.7899A>T p.L2633= | Silent (SNP) | VAF 8/59 reads (14%) | called by muse, mutect2, varscan2
- BCAN | c.825G>A p.A275= | Silent (SNP) | VAF 14/45 reads (31%) | catalogued as rs776798315, COSV61255405; called by muse, mutect2, varscan2
- CD4 | c.573G>A p.K191= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV50590842; called by muse, mutect2, varscan2
- CDH10 | c.2070T>C p.I690= | Silent (SNP) | VAF 16/28 reads (57%) | called by muse, mutect2, varscan2
- CIC | c.123C>G p.V41= | Silent (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- CPZ | c.1575C>G p.V525= (on ENST00000360986 / NM_001014447.3; = p.V514= on NM_003652.3) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs760220072; called by muse, mutect2, varscan2
- DACH2 | c.1200C>G p.S400= | Silent (SNP) | VAF 15/20 reads (75%) | called by muse, mutect2, varscan2
- DYSF | c.1108C>A p.R370= | Silent (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- DYSF | c.5115C>T p.F1705= | Silent (SNP) | VAF 13/35 reads (37%) | called by muse, mutect2, varscan2
- EMP3 | c.441C>T p.P147= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs377482803; called by muse, mutect2, varscan2
- GIT2 | c.1710G>T p.S570= | Silent (SNP) | VAF 13/29 reads (45%) | called by muse, mutect2
- GJA1 | c.363C>T p.V121= | Silent (SNP) | VAF 24/70 reads (34%) | called by muse, mutect2, varscan2
- IL17RA | c.202C>T p.L68= | Silent (SNP) | VAF 17/49 reads (35%) | called by muse, mutect2, varscan2
- JPH4 | c.1248G>A p.L416= | Silent (SNP) | VAF 4/33 reads (12%) | called by muse, mutect2, varscan2
- KMT2C | c.12798A>G p.Q4266= | Silent (SNP) | VAF 36/66 reads (55%) | catalogued as rs1013645708; called by muse, mutect2, varscan2
- LCT | c.2022G>C p.L674= | Silent (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- LENG9 | c.990C>T p.N330= | Silent (SNP) | VAF 17/68 reads (25%) | catalogued as rs1301473690; called by muse, mutect2, varscan2
- MNAT1 | c.321C>T p.F107= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2
- NAV3 | c.1503A>G p.K501= | Silent (SNP) | VAF 11/31 reads (35%) | called by muse, mutect2, varscan2
- NLRP7 | c.240C>G p.L80= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- NOX3 | c.462C>T p.L154= | Silent (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- OBSCN | c.11082C>T p.Y3694= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- PKD1 | c.3591G>A p.V1197= | Silent (SNP) | VAF 43/131 reads (33%) | called by muse, mutect2, varscan2
- RNF139 | c.798C>T p.F266= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as COSV52678902; called by muse, mutect2, varscan2
- RNF25 | c.990C>T p.G330= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs754094338, COSV99829295; called by muse, mutect2, varscan2
- RPP21 | c.15G>A p.V5= | Silent (SNP) | VAF 11/39 reads (28%) | called by muse, mutect2, varscan2
- SEC24C | c.1854A>T p.V618= | Silent (SNP) | VAF 17/56 reads (30%) | called by muse, mutect2, varscan2
- SERPINB2 | c.795C>T p.F265= | Silent (SNP) | VAF 8/76 reads (11%) | catalogued as COSV100208681; called by muse, mutect2
- SLC25A6 | c.630C>T p.I210= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs780007250, COSV58431896; called by muse, mutect2, varscan2
- STUB1 | c.660G>A p.E220= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as rs941757224; called by muse, mutect2, varscan2
- TKTL2 | c.123G>A p.S41= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV54918497; called by muse, mutect2, varscan2
- TTN | c.16687C>T p.L5563= (on ENST00000591111; = p.L4636= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/66 reads (36%) | catalogued as rs1414423068; called by muse, mutect2, varscan2
- ZC3H12D | c.27C>T p.F9= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as COSV101116790, COSV66324220; called by muse, varscan2
- AMT | c.*194T>C | 3'UTR (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
- OR2W5 | n.1011G>T | RNA (SNP) | VAF 23/81 reads (28%) | called by muse, mutect2, varscan2
- PRSS3 | c.-107T>A | 5'UTR (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- RPL17-C18orf32 | c.81+99G>A | Intron (SNP) | VAF 5/48 reads (10%) | called by muse, mutect2, varscan2
- STARD13 | c.170-18389C>A | Intron (SNP) | VAF 14/28 reads (50%) | called by mutect2, varscan2
